Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6620, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6620-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] female

Date of Event [REDACTED]

PRE-OP DIAGNOSIS: Blood in stool.

POST-OP DIAGNOSIS: Rectal mass.

PROCEDURE: Not provided.

FINAL DIAGNOSIS:

RECTUM, MASS, BIOPSY [REDACTED]

INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA INVOLVING COLONIC MUCOSA.

[REDACTED] TCGA - CI - 6620

Source: NCI Genomic Data Commons file af00c3fb-e803-4215-a11f-d8c5e52853a0 (TCGA-CI-6620.103605FA-BFBE-49B0-AFEA-3F8B60A3F2A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).